Somatic mutation profile of tumor specimen TCGA-M7-A720-01A (aliquot TCGA-M7-A720-01A-12D-A32B-08) from TCGA case TCGA-M7-A720, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.8 years (19,642 days).
Specimen TCGA-M7-A720-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed2d9d69-7ab4-4b11-8d98-54d70b604e1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-M7-A720-10A (Blood Derived Normal), aliquot TCGA-M7-A720-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96eef33b-fb1b-4ba3-9629-b8c04ca482d7

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AURKB | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV100298864; called by muse, mutect2
- SLC9C1 | c.2519A>G p.N840S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs764542610, COSV99998640; called by muse, mutect2
- MEOX1 | c.512C>G p.A171G | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- MORN4 | c.417G>A p.K139= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100167422; called by muse, mutect2
